Somatic mutation profile of tumor specimen MMRF_1086_1_BM_CD138pos (aliquot MMRF_1086_1_BM_CD138pos_T2_TSE61_K02708) from MMRF case MMRF_1086, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.0 years (24,467 days).
Specimen MMRF_1086_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b7c365b-a4b6-43b3-9019-4e3c6bc939e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1086_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1086_1_PB_Whole_C1_TSE61_K02715; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/44025b02-f7d3-4e6e-9d63-e5396449ff1c

The open-access MAF lists 86 somatic variants for this specimen: 38 protein-altering or splice-affecting, 13 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, 3'UTR 25, Silent 13, RNA 4, 5'Flank 3, 5'UTR 3, Nonsense Mutation 2, Translation Start Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F13A1 | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 52/97 reads (54%) | catalogued as rs121913065, CM930201, COSV53553799, COSV53554927; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BICC1 | c.1843T>A p.S615T | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV54064349; called by muse, mutect2, varscan2
- CADPS2 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 61/84 reads (73%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as rs746180204; called by muse, mutect2, varscan2
- CDC42BPA | c.2609G>A p.R870H | Missense Mutation (SNP) | VAF 62/129 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs772856713, COSV62020082; called by muse, mutect2, varscan2
- F9 | c.195G>A p.M65I | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763568424, COSV54382844; called by muse, mutect2, varscan2
- FAT1 | c.1785T>G p.D595E | Missense Mutation (SNP) | VAF 98/152 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1186176635; called by muse, mutect2, varscan2
- FOCAD | c.3053G>A p.G1018E | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1361618312; called by muse, varscan2
- NIBAN2 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 55/225 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs567489926; called by muse, mutect2, varscan2
- OTUD6A | c.817A>C p.T273P | Missense Mutation (SNP) | VAF 55/96 reads (57%) | SIFT deleterious (0.05); PolyPhen benign (0.107); catalogued as COSV100611040; called by muse, mutect2, varscan2
- PIK3CA | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 8/184 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); catalogued as COSV55935970; called by muse, mutect2
- PRSS53 | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs754261424; called by muse, mutect2, varscan2
- PTPRN2 | c.2809C>T p.R937C | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs752527922; called by muse, mutect2, varscan2
- SEPTIN11 | c.719C>T p.T240I | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.285); catalogued as rs759768495; called by muse, mutect2, varscan2
- SNX5 | c.857A>G p.D286G | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1034021590; called by muse, mutect2
- SRGAP3 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1463819968; called by muse, mutect2, varscan2
- TRPC6 | c.1764del p.S589Lfs*5 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | catalogued as COSV60255036; called by mutect2, pindel, varscan2
- UBE2J1 | c.644C>G p.P215R | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs112892732; called by muse, mutect2, varscan2
- APEX2 | c.1220C>T p.S407F | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- CDK5RAP2 | c.3113A>G p.E1038G | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.539); called by muse, mutect2
- DOCK11 | c.4063G>C p.A1355P | Missense Mutation (SNP) | VAF 62/193 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- FAM160A2 | c.974A>G p.Y325C | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- IGBP1 | c.345G>T p.Q115H | Missense Mutation (SNP) | VAF 65/127 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IRF1 | c.922A>G p.S308G | Missense Mutation (SNP) | VAF 77/254 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- MED13L | c.2775G>T p.K925N | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); called by muse, mutect2
- MYO15A | c.4762G>A p.D1588N | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO15A | c.4763A>C p.D1588A | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NMUR2 | c.1145T>C p.F382S | Missense Mutation (SNP) | VAF 102/164 reads (62%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.056); called by muse, mutect2
- NUMA1 | c.5164A>T p.I1722F | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); called by muse, varscan2
- NUP160 | c.1070G>A p.G357E | Missense Mutation (SNP) | VAF 108/169 reads (64%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, varscan2
- PRAMEF17 | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 22/490 reads (4%) | SIFT tolerated (0.98); PolyPhen benign (0.023); called by muse, mutect2
- RTL5 | c.1289G>A p.G430E | Missense Mutation (SNP) | VAF 7/181 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2
- SPECC1 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRRAP | c.9946T>A p.S3316T (on ENST00000359863 / NM_001244580.1; = p.S3287T on NM_003496.3) | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- TSPAN17 | c.987T>A p.F329L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); called by muse, varscan2
- USP19 | c.400G>C p.G134R | Missense Mutation (SNP) | VAF 70/206 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VSIG10L | c.284C>A p.S95* | Nonsense Mutation (SNP) | VAF 40/148 reads (27%) | called by muse, mutect2, varscan2
- ZNF467 | c.1171C>G p.L391V | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.049); called by muse, varscan2
- ZSCAN23 | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- AKAP6 | c.1602T>G p.L534= | Silent (SNP) | VAF 42/81 reads (52%) | called by muse, mutect2, varscan2
- DOCK4 | c.5871G>A p.R1957= | Silent (SNP) | VAF 9/143 reads (6%) | called by muse, mutect2
- E2F5 | c.957T>G p.P319= | Silent (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
- FOCAD | c.3054G>T p.G1018= | Silent (SNP) | VAF 13/74 reads (18%) | called by muse, varscan2
- KIAA1328 | c.1320T>C p.N440= | Silent (SNP) | VAF 72/150 reads (48%) | catalogued as rs1217195220; called by muse, mutect2, varscan2
- KRTAP2-2 | c.72C>T p.C24= | Silent (SNP) | VAF 21/50 reads (42%) | called by muse, mutect2, varscan2
- NUMA1 | c.5109A>T p.A1703= | Silent (SNP) | VAF 40/122 reads (33%) | called by muse, varscan2
- PLXNA2 | c.951G>A p.K317= | Silent (SNP) | VAF 39/94 reads (41%) | catalogued as rs1455810449; called by muse, mutect2, varscan2
- RASGRF1 | c.3429G>A p.R1143= | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as COSV60212359; called by muse, mutect2, varscan2
- SLIT1 | c.3642T>C p.V1214= | Silent (SNP) | VAF 48/131 reads (37%) | called by muse, mutect2, varscan2
- TAP1 | c.15C>T p.L5= | Silent (SNP) | VAF 12/87 reads (14%) | called by muse, mutect2
- TLR5 | c.1500A>G p.G500= | Silent (SNP) | VAF 92/179 reads (51%) | called by muse, mutect2, varscan2
- ZNF540 | c.537G>T p.G179= | Silent (SNP) | VAF 116/188 reads (62%) | called by muse, varscan2
- AKR7A3 | c.*61C>G | 3'UTR (SNP) | VAF 10/203 reads (5%) | called by muse, mutect2
- BTBD7 | c.*264T>C | 3'UTR (SNP) | VAF 34/74 reads (46%) | called by muse, mutect2, varscan2
- BX322639.1 | n.6056C>T | RNA (SNP) | VAF 15/39 reads (38%) | catalogued as rs577718983; called by muse, mutect2, varscan2
- C8orf86 | n.2213_2215del | RNA (DEL) | VAF 57/102 reads (56%) | catalogued as rs1267869728; called by mutect2, pindel, varscan2
- CCRL2 | c.-98G>A | 5'UTR (SNP) | VAF 32/83 reads (39%) | catalogued as rs573204763; called by muse, mutect2, varscan2
- CDH19 | c.*492C>A | 3'UTR (SNP) | VAF 12/21 reads (57%) | called by muse, mutect2, varscan2
- CLDN2 | c.*358C>T | 3'UTR (SNP) | VAF 28/135 reads (21%) | called by muse, mutect2, varscan2
- CYP11B2 | c.*801C>T | 3'UTR (SNP) | VAF 148/349 reads (42%) | called by muse, mutect2, varscan2
- ELK1 | c.*99A>G | 3'UTR (SNP) | VAF 54/104 reads (52%) | called by muse, mutect2, varscan2
- ERI1 | c.*762A>T | 3'UTR (SNP) | VAF 37/89 reads (42%) | called by muse, mutect2, varscan2
- FAM30A | n.6090_6093del | RNA (DEL) | VAF 99/118 reads (84%) | called by mutect2, pindel, varscan2
- FOXN2 | c.*2586T>C | 3'UTR (SNP) | VAF 114/190 reads (60%) | called by muse, mutect2, varscan2
- GPR19 | c.-243T>C | 5'UTR (SNP) | VAF 82/82 reads (100%) | called by muse, mutect2, varscan2
- INPP4B | c.*317G>T | 3'UTR (SNP) | VAF 9/236 reads (4%) | called by muse, mutect2
- MIR7158 | chr2:5973564 A>C | 5'Flank (SNP) | VAF 28/50 reads (56%) | called by muse, mutect2, varscan2
- MPPED1 | c.*929G>T | 3'UTR (SNP) | VAF 37/77 reads (48%) | called by muse, mutect2, varscan2
- MSH2 | c.*186G>C | 3'UTR (SNP) | VAF 75/124 reads (60%) | called by muse, mutect2, varscan2
- NR1H2 | c.*401A>G | 3'UTR (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- NUDT12 | c.*1522T>G | 3'UTR (SNP) | VAF 56/179 reads (31%) | called by muse, mutect2, varscan2
- NUP50 | c.*2528_*2561delinsAAACCTGTGTAACCATCTCATCCTTTTGGCCC | 3'UTR (DEL) | VAF 4/41 reads (10%) | called by pindel, varscan2*
- PAXIP1 | chr7:155004737 A>G | 5'Flank (SNP) | VAF 26/92 reads (28%) | called by muse, mutect2, varscan2
- PCMTD1 | c.*1925_*1926insGTT | 3'UTR (INS) | VAF 20/110 reads (18%) | called by pindel, varscan2
- PDE3A | c.*183G>A | 3'UTR (SNP) | VAF 36/79 reads (46%) | called by muse, mutect2, varscan2
- POLR1E | chr9:37485957 C>G | 5'Flank (SNP) | VAF 13/35 reads (37%) | catalogued as rs531914693; called by muse, varscan2
- POU2F3 | c.*974G>A | 3'UTR (SNP) | VAF 11/36 reads (31%) | catalogued as COSV99500810; called by mutect2, varscan2
- RAPGEF1 | c.*425G>T | 3'UTR (SNP) | VAF 5/99 reads (5%) | called by muse, mutect2
- RNF145 | c.*511A>G | 3'UTR (SNP) | VAF 28/116 reads (24%) | called by muse, mutect2, varscan2
- RPA3 | c.-148G>C | 5'UTR (SNP) | VAF 6/138 reads (4%) | called by muse, mutect2
- SLC25A22 | c.*229T>C | 3'UTR (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- SLMAP | c.*435T>A | 3'UTR (SNP) | VAF 9/111 reads (8%) | called by muse, mutect2
- SPATA5 | c.*686G>A | 3'UTR (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2, varscan2
- WDFY3 | c.*1994C>A | 3'UTR (SNP) | VAF 64/215 reads (30%) | called by muse, mutect2, varscan2
- XRCC6P5 | n.328A>T | RNA (SNP) | VAF 42/196 reads (21%) | called by muse, mutect2, varscan2
- ZNF681 | c.*3543A>G | 3'UTR (SNP) | VAF 45/148 reads (30%) | catalogued as rs1333253498; called by muse, mutect2, varscan2
- ZNF716 | c.*1110A>T | 3'UTR (SNP) | VAF 37/118 reads (31%) | catalogued as COSV70783585; called by muse, mutect2, varscan2
